MMRF case MMRF_1839 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/73f46ad6-df9e-4525-b1fa-271cb85ba3dc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.8 years (24,384 days); ISS stage: III; Days to last known disease status: 1,080 days (3.0 years); Days to last follow up: 1,080 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 102 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 240 days; Days to treatment end: 898 days (2.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 240 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13: M Protein 8.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 82.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 96.4 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 12.1 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 4.84 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.43 mmol/L; Albumin 26 g/L; Total Protein 14.4 g/dL; Glucose 6.05 mmol/L.
- Day 80 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 0.268 g/L; Immunoglobulin M 0.191 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.18 mmol/L.
- Day 155 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.3 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.288 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 342 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 7.48 mmol/L.
- Day 261: M Protein 0.21 g/dL.
- Day 336 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 3.83 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 5.46 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 4.4 mmol/L.
- Day 442: M Protein 0 g/dL.
- Day 529 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 5.24 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 5.01 mmol/L.
- Day 611 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 5.56 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 5.9 g/dL; Glucose 4.51 mmol/L.
- Day 674: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 6.94 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 786: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 6.09 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 5.4 g/dL; Glucose 4.51 mmol/L.
- Day 898 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.1 mg/dL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.18 mmol/L.
- Day 988 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.07 mg/dL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.29 mmol/L.
- Day 1,080 (ECOG 1): M Protein 0 g/dL; Hemoglobin 7.32 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 3.52 mmol/L.

Other clinical attributes
- Day -13: Weight: 90 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1839_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1839_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
